HCMI case HCM-BROD-0035-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fa30fc7f-90b6-4ca0-93b6-1351eae9dfc8

Demographics
Sex at birth: male; Race: white; Year of birth: 2002; Vital status: Dead; Days to death: 641 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Undifferentiated sarcoma (the primary disease): ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.9; Tissue or organ of origin: Bone, NOS; Classification of tumor: primary; Age at diagnosis: 9.8 years (3,585 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Prior malignancy: yes; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Ifosfamide + Vincristine; Treatment intent type: Neoadjuvant; Days to treatment start: 63 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Etoposide; Treatment intent type: Neoadjuvant; Days to treatment start: 63 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 449 days (1.2 years); Days to treatment end: 516 days (1.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel + Gemcitabine Hydrochloride; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 510 days (1.4 years); Days to treatment end: 543 days (1.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 557 days (1.5 years); Days to treatment end: 588 days (1.6 years).
   Recorded as not given: adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.
2. Metastasis of the bone (histology not recorded by GDC). ICD-10 code: C79.3; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 11.1 years (4,038 days); Days to diagnosis: 453 days (1.2 years).

Follow-up (1 entry)
- Days to follow up: 633 days (1.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 31 kg; Height: 137 cm; BMI: 17.

Exposures
- Alcohol drinks per day: 0.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0035-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0035-C49-06A-02-S2-HE: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0035-C49-06A-02-S1-HE: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0035-C49-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0035-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 7.
